CCDI case PBCALA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/9984855f-79ac-495d-9b9b-6560e2356423

Demographics
Sex at birth: female.

Diagnoses (1)
1. Abdominal fibromatosis: ICD-O-3 morphology code: 8822/1; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 17.4 years (6,357 days).

Biospecimens (4 samples)
- Sample 0DMKKJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DMKKV, 0DMKN8 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMN2B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
